Somatic mutation profile of tumor specimen TCGA-BA-A6DJ-01A (aliquot TCGA-BA-A6DJ-01A-11D-A30E-08) from TCGA case TCGA-BA-A6DJ, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Gum, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 62.9 years (22,967 days).
Specimen TCGA-BA-A6DJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3d7a662d-13cd-4260-8e1f-d9f799ac75b6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BA-A6DJ-10A (Blood Derived Normal), aliquot TCGA-BA-A6DJ-10A-01D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a217a230-4627-4ca6-bd79-3c0cf67eca05

The open-access MAF lists 280 somatic variants for this specimen: 196 protein-altering or splice-affecting, 77 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 170, Silent 77, Nonsense Mutation 10, Frame Shift Del 4, Frame Shift Ins 4, Splice Site 4, 5'UTR 3, RNA 2, In Frame Ins 1, 5'Flank 1, Splice Region 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCND1 | c.860C>T p.P287L | Missense Mutation (SNP) | VAF 11/41 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57119102, COSV57119569, COSV57120578; called by muse, mutect2, varscan2
- HRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 47/176 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as rs121913233, COSV54236656, COSV54236691, COSV54238654; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RAC1 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 11/63 reads (17%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.713); catalogued as rs1057519874, COSV61821563, COSV61823187; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ACRBP | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.077); catalogued as COSV99976232; called by muse, mutect2, varscan2
- ACTN3 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.218); catalogued as COSV101557863; called by muse, mutect2, varscan2
- ADAM28 | c.2027C>T p.A676V | Missense Mutation (SNP) | VAF 49/228 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.746); catalogued as rs747833359; called by muse, mutect2, varscan2
- ADAMTS17 | c.2610G>T p.W870C | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99171361; called by muse, mutect2, varscan2
- ADAMTS19 | c.1924G>T p.A642S | Missense Mutation (SNP) | VAF 49/204 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.025); catalogued as COSV99179730; called by muse, mutect2, varscan2
- ADAMTS6 | c.83C>T p.S28L | Missense Mutation (SNP) | VAF 49/221 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as COSV101125277; called by muse, mutect2, varscan2
- ADAR | c.425G>A p.R142K | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV99426428; called by muse, mutect2, varscan2
- ADCY2 | c.2278G>A p.E760K | Missense Mutation (SNP) | VAF 47/177 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as COSV100602145, COSV100603543; called by muse, mutect2, varscan2
- ADCY8 | c.19C>T p.R7C | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.973); catalogued as rs1403776150, COSV99651382; called by muse, mutect2, varscan2
- ADNP2 | c.1979C>T p.P660L | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV100081093; called by muse, mutect2, varscan2
- AHCTF1 | c.5330G>C p.R1777T (on ENST00000366508; = p.R1751T on NM_015446.5) | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.045); catalogued as COSV100404164; called by muse, mutect2, varscan2
- ALPG | c.872G>C p.G291A | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.023); catalogued as COSV99779428; called by muse, mutect2, varscan2
- ANKRD44 | c.1816C>A p.L606M | Missense Mutation (SNP) | VAF 12/310 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99985659; called by muse, mutect2
- ANKRD52 | c.58G>C p.D20H | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.417); catalogued as COSV57287150; called by muse, mutect2
- AP2B1 | c.154C>G p.P52A | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.035); catalogued as COSV51998355, COSV99251486; called by muse, mutect2, varscan2
- AP3S2 | c.550A>C p.I184L | Missense Mutation (SNP) | VAF 57/196 reads (29%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.007); catalogued as COSV100318589; called by muse, mutect2, varscan2
- ARMCX6 | c.316C>G p.P106A | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100726244, COSV100726247; called by muse, mutect2
- ATF4 | c.35T>C p.L12S | Missense Mutation (SNP) | VAF 36/153 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.274); catalogued as COSV100307784, COSV57479644; called by muse, mutect2, varscan2
- ATRNL1 | c.4108C>T p.H1370Y | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.838); catalogued as rs1555125091, COSV100371472; called by muse, mutect2, varscan2
- ATXN3 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV100515089; called by muse, mutect2, varscan2
- BCAR3 | c.2326G>C p.E776Q | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99550859, COSV99551066; called by muse, mutect2, varscan2
- BCAS2 | c.601C>T p.Q201* | Nonsense Mutation (SNP) | VAF 39/147 reads (27%) | catalogued as rs776662991, COSV101058648; called by muse, mutect2, varscan2
- BCL9L | c.3167C>T p.P1056L | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.281); catalogued as COSV99419831; called by muse, mutect2, varscan2
- BRWD3 | c.1975G>C p.D659H | Missense Mutation (SNP) | VAF 35/58 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100956347, COSV64750551; called by muse, mutect2, varscan2
- BSDC1 | c.565C>T p.R189W | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777450364, COSV61982083; called by muse, mutect2, varscan2
- BTNL2 | c.863A>C p.Y288S | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.8); PolyPhen benign (0.2); catalogued as COSV100896161; called by muse, mutect2, varscan2
- BTNL8 | c.160C>T p.R54W | Missense Mutation (SNP) | VAF 37/153 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs776813203, COSV99180404; called by muse, mutect2, varscan2
- C1orf94 | c.640G>A p.A214T (on ENST00000488417 / NM_001134734.2; = p.A24T on NM_032884.5) | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs202207825, COSV64913085; called by muse, mutect2, varscan2
- C6orf89 | c.106G>A p.E36K (on ENST00000373685; = p.E43K on NM_152734.4) | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100769721, COSV100769751; called by muse, mutect2, varscan2
- C9orf153 | c.289C>G p.P97A | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.104); catalogued as COSV100188731; called by muse, mutect2, varscan2
- CABP1 | c.743G>A p.R248Q (on ENST00000316803 / NM_001033677.1; = p.R45Q on NM_004276.5) | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.35); catalogued as COSV99974775; called by muse, mutect2, varscan2
- CAMK2B | c.944C>T p.S315L | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV99323315; called by muse, mutect2, varscan2
- CBX2 | c.1522G>A p.V508I | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs781926428, COSV53969553; called by muse, mutect2, varscan2
- CCDC116 | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 37/185 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs147529801; called by muse, mutect2, varscan2
- CCDC18 | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV100159827; called by muse, mutect2, varscan2
- CLCA2 | c.549C>G p.F183L | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as COSV100991640; called by muse, mutect2, varscan2
- CLEC3A | c.173A>G p.E58G (on ENST00000651443; = p.E49G on NM_005752.6) | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV100222316; called by muse, mutect2, varscan2
- CNOT1 | c.2572C>T p.H858Y | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as COSV99800836; called by muse, mutect2, varscan2
- CNTNAP3 | c.2003C>T p.S668F | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as COSV99905363; called by muse, varscan2
- COL11A1 | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.997); catalogued as rs146954848, COSV62183267; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL14A1 | c.1321+1G>A p.X441_splice | Splice Site (SNP) | VAF 25/64 reads (39%) | catalogued as rs775204866, COSV52852671; called by muse, mutect2, varscan2
- CTIF | c.1648G>A p.A550T | Missense Mutation (SNP) | VAF 45/161 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.734); catalogued as rs778674002, COSV99838174; called by muse, mutect2, varscan2
- CYP1A1 | c.239C>G p.S80C | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.076); catalogued as COSV101122362; called by muse, mutect2, varscan2
- DCLK1 | c.68G>A p.R23Q | Missense Mutation (SNP) | VAF 63/181 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs1376151056, COSV55204542; called by muse, mutect2, varscan2
- DIP2C | c.2645C>A p.A882E | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.14); catalogued as COSV99793093; called by muse, mutect2, varscan2
- DNAJC21 | c.1172A>T p.Q391L | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.083); catalogued as COSV100331545; called by muse, mutect2, varscan2
- EIF5A2 | c.150G>T p.K50N | Missense Mutation (SNP) | VAF 63/218 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV99858763; called by muse, mutect2, varscan2
- EMID1 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs202038784, COSV100469182; called by muse, mutect2, varscan2
- EPN1 | c.1618C>G p.P540A (on ENST00000270460 / NM_001321263.1; = p.P514A on NM_013333.3) | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as COSV99322198; called by muse, mutect2, varscan2
- EXOC2 | c.1790-1G>A p.X597_splice | Splice Site (SNP) | VAF 7/30 reads (23%) | catalogued as COSV100034000; called by muse, mutect2
- EZH2 | c.565G>A p.D189N | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV100236313; called by muse, mutect2
- FAM170A | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs373177857; called by muse, mutect2, varscan2
- FAM78A | c.116C>T p.T39M | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV100953433; called by muse, mutect2, varscan2
- FAT4 | c.11380C>T p.R3794W | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs201859188; called by muse, mutect2, varscan2
- FLG | c.217G>C p.E73Q | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100911914; called by muse, mutect2, varscan2
- FSHR | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs372147824; called by muse, mutect2, varscan2
- GANAB | c.1342C>G p.Q448E | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100648153, COSV60466060; called by muse, mutect2, varscan2
- GATA6 | c.1568C>G p.S523* | Nonsense Mutation (SNP) | VAF 26/125 reads (21%) | catalogued as COSV99333357; called by muse, mutect2, varscan2
- GATM | c.269C>T p.P90L | Missense Mutation (SNP) | VAF 44/169 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as rs1261342154, COSV101188373; called by muse, mutect2, varscan2
- GGA1 | c.133C>G p.P45A | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as COSV100289830; called by muse, mutect2, varscan2
- GIGYF2 | c.596C>G p.S199* | Nonsense Mutation (SNP) | VAF 31/77 reads (40%) | catalogued as COSV101004412, COSV65249374; called by muse, mutect2, varscan2
- GNAI1 | c.591-1G>C p.X197_splice | Splice Site (SNP) | VAF 26/98 reads (27%) | catalogued as COSV100650587; called by muse, mutect2, varscan2
- GNPTAB | c.1963C>T p.P655S | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs940673327, COSV100172259; called by muse, mutect2, varscan2
- GPS2 | c.752C>G p.S251C | Missense Mutation (SNP) | VAF 44/165 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.753); catalogued as COSV100223182; called by muse, mutect2, varscan2
- GPS2 | c.641C>T p.S214L | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.152); catalogued as rs1324992597, COSV59751807; called by muse, mutect2, varscan2
- GPS2 | c.32C>G p.S11C | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as rs1046741911, COSV100223185; called by muse, varscan2
- GREB1 | c.3113C>T p.S1038F | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99303459; called by muse, mutect2, varscan2
- GRM1 | c.2444C>T p.T815I | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99268073; called by muse, mutect2, varscan2
- GRM3 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 48/147 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64469035, COSV64474293; called by muse, mutect2, varscan2
- HERC1 | c.12869G>A p.G4290E | Missense Mutation (SNP) | VAF 67/252 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.652); catalogued as rs748059385, COSV101496770; called by muse, mutect2, varscan2
- HEY2 | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.806); catalogued as rs769963246, COSV64239865; called by muse, mutect2, varscan2
- HLA-B | c.721T>G p.W241G | Missense Mutation (SNP) | VAF 41/193 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV101318178, COSV69521251; called by muse, varscan2
- HLX | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); catalogued as rs1258329717, COSV100854597; called by muse, mutect2, varscan2
- HTR3A | c.304T>G p.F102V | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100248539; called by muse, mutect2, varscan2
- IGDCC4 | c.2782G>C p.E928Q | Missense Mutation (SNP) | VAF 78/269 reads (29%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.959); catalogued as rs751629777, COSV100733057; called by muse, mutect2, varscan2
- IQGAP3 | c.1742G>A p.G581E | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.054); catalogued as COSV100752249, COSV100752287; called by muse, mutect2, varscan2
- KDR | c.3062C>T p.S1021L | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55774920; called by muse, mutect2, varscan2
- KIF23 | c.2138G>A p.R713H | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.247); catalogued as rs370717019, COSV99532572; called by muse, mutect2, varscan2
- KLHL41 | c.1361G>A p.G454E | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99500509; called by muse, mutect2, varscan2
- KMT2B | c.3743G>A p.R1248H | Missense Mutation (SNP) | VAF 63/234 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99720255; called by muse, mutect2, varscan2
- LRFN3 | c.127G>A p.V43M | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.139); catalogued as rs1472841083, COSV99873343, COSV99873507; called by muse, mutect2, varscan2
- MAMDC4 | c.475G>C p.E159Q | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.968); catalogued as COSV99915806; called by muse, mutect2, varscan2
- MAP4K1 | c.1625C>T p.T542I | Missense Mutation (SNP) | VAF 49/220 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV101204329; called by muse, mutect2, varscan2
- MAPK7 | c.340A>G p.I114V | Missense Mutation (SNP) | VAF 43/154 reads (28%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.968); catalogued as COSV100219034; called by muse, mutect2, varscan2
- MCM3AP | c.5573A>T p.E1858V | Missense Mutation (SNP) | VAF 7/162 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.024); catalogued as COSV99387290; called by muse, mutect2
- MCM3AP | c.5572G>A p.E1858K | Missense Mutation (SNP) | VAF 7/163 reads (4%) | SIFT tolerated (0.46); PolyPhen benign (0.027); catalogued as COSV99387292; called by muse, mutect2
- MCU | c.479T>C p.V160A | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV64065058; called by muse, mutect2, varscan2
- MFSD8 | c.46G>A p.D16N | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.163); catalogued as rs752624076, COSV99614591; called by muse, mutect2, varscan2
- MPHOSPH8 | c.694A>G p.K232E | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.162); catalogued as COSV100825185; called by muse, mutect2, varscan2
- MUC17 | c.3703G>C p.E1235Q | Missense Mutation (SNP) | VAF 199/714 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.857); catalogued as COSV100074442, COSV60301132, COSV60302939; called by muse, mutect2, varscan2
- MYCT1 | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 40/145 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs17852097, COSV65891766; called by muse, mutect2, varscan2
- MYH9 | c.1588G>A p.E530K | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53382462, COSV53382648; called by muse, mutect2, varscan2
- NAP1L1 | c.421G>T p.E141* | Nonsense Mutation (SNP) | VAF 9/33 reads (27%) | catalogued as COSV53873569, COSV99673979; called by muse, mutect2, varscan2
- NAV3 | c.3442G>T p.G1148C | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV99893918; called by muse, mutect2, varscan2
- NCOA6 | c.3248A>T p.Q1083L | Missense Mutation (SNP) | VAF 46/155 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV100750231; called by muse, mutect2, varscan2
- NECAB2 | c.808G>T p.D270Y | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59420313, COSV59422069; called by muse, mutect2, varscan2
- NIN | c.1654G>C p.D552H | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99814557; called by muse, mutect2, varscan2
- NRXN3 | c.3034C>G p.R1012G (on ENST00000335750 / NM_001330195.2; = p.R639G on NM_004796.6) | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs774467995, COSV100207006; called by muse, mutect2, varscan2
- NUTM2F | c.836C>T p.A279V | Missense Mutation (SNP) | VAF 36/206 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as rs761896962, COSV53558483; called by muse, mutect2, varscan2
- NVL | c.766G>C p.E256Q | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.077); catalogued as COSV99894874; called by muse, mutect2
- ODF2 | c.1817C>T p.T606M (on ENST00000434106 / NM_153433.2; = p.T582M on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.685); catalogued as rs751181164, COSV100654870; called by muse, mutect2, varscan2
- OR51B6 | c.278G>C p.G93A | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV100971733, COSV66512944; called by muse, mutect2, varscan2
- OR5D14 | c.512C>G p.S171C | Missense Mutation (SNP) | VAF 12/260 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100162235, COSV100162531, COSV59456933; called by muse, mutect2
- OR5H1 | c.740C>T p.S247F | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.35); catalogued as rs375548200, COSV63402807; called by muse, mutect2, varscan2
- OR6N2 | c.329C>T p.S110F | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV100210363; called by muse, mutect2, varscan2
- P2RX4 | c.579C>G p.I193M | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100465220; called by muse, mutect2, varscan2
- P4HA1 | c.280G>T p.E94* | Nonsense Mutation (SNP) | VAF 42/210 reads (20%) | catalogued as COSV99697078; called by muse, mutect2, varscan2
- PDZD2 | c.1711C>G p.Q571E | Missense Mutation (SNP) | VAF 8/173 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as COSV56877947; called by muse, mutect2
- PHLDB2 | c.792G>T p.E264D | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV101208605, COSV67310822; called by muse, mutect2, varscan2
- PKDREJ | c.4642C>G p.Q1548E | Missense Mutation (SNP) | VAF 66/275 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99479300; called by muse, mutect2, varscan2
- PKHD1L1 | c.11057G>C p.R3686T | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV101006616; called by muse, mutect2, varscan2
- PLXDC1 | c.1010G>A p.R337H | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs143709538; called by muse, mutect2, varscan2
- PLXNB2 | c.2510G>C p.R837T | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.033); catalogued as COSV100834210; called by muse, mutect2, varscan2
- PPARGC1B | c.451G>C p.D151H | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100494998; called by muse, mutect2, varscan2
- PPP2CB | c.40dup p.V14Gfs*8 | Frame Shift Ins (INS) | VAF 9/35 reads (26%) | catalogued as rs774677653; called by mutect2, pindel, varscan2
- PPP6R1 | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.043); catalogued as COSV101336999; called by muse, mutect2
- PTPRM | c.1847C>A p.A616E | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100159226; called by muse, mutect2, varscan2
- RABEP1 | c.400C>T p.L134F | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.72); PolyPhen benign (0.105); catalogued as COSV99336392; called by muse, mutect2, varscan2
- RAD52 | c.875C>G p.P292R | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.62); catalogued as rs746435057, COSV99942645; called by muse, mutect2, varscan2
- RBBP7 | c.97C>G p.L33V | Missense Mutation (SNP) | VAF 42/68 reads (62%) | SIFT tolerated (0.12); PolyPhen benign (0.043); catalogued as COSV101198318; called by muse, mutect2, varscan2
- REL | c.149T>C p.I50T | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99692279; called by muse, mutect2, varscan2
- REV3L | c.9065C>T p.S3022L | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs763030770, COSV100725526; called by muse, mutect2, varscan2
- RFX6 | c.1040G>A p.R347K | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); catalogued as COSV60583724; called by muse, mutect2, varscan2
- RIMBP2 | c.2692G>A p.E898K | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55469856; called by muse, varscan2
- RIN1 | c.523G>C p.E175Q | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV100254865; called by muse, mutect2, varscan2
- RIN2 | c.971T>C p.L324P (on ENST00000255006 / NM_001242581.1; = p.L275P on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99657607; called by muse, mutect2, varscan2
- RIOK2 | c.60G>C p.L20F | Missense Mutation (SNP) | VAF 45/216 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1056388437, COSV51615528, COSV99300143; called by muse, mutect2, varscan2
- RPS6KB1 | c.989G>C p.R330T | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56677825, COSV99847683; called by muse, mutect2, varscan2
- RPS6KC1 | c.1213C>A p.Q405K | Missense Mutation (SNP) | VAF 48/246 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV100874023, COSV104423814; called by muse, mutect2, varscan2
- RTL9 | c.428T>C p.M143T | Missense Mutation (SNP) | VAF 63/105 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.121); catalogued as COSV101511759; called by muse, mutect2, varscan2
- RYR2 | c.4975C>T p.R1659W | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1483097607, COSV63681954; called by muse, mutect2, varscan2
- SAFB | c.2309C>G p.S770* | Nonsense Mutation (SNP) | VAF 22/82 reads (27%) | catalogued as COSV99413080; called by muse, mutect2, varscan2
- SAFB2 | c.116G>A p.R39Q | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99385923; called by muse, mutect2, varscan2
- SAGE1 | c.2551G>C p.E851Q | Missense Mutation (SNP) | VAF 60/107 reads (56%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.87); catalogued as COSV100187687; called by muse, mutect2, varscan2
- SGSH | c.1389G>A p.M463I | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100413545; called by muse, mutect2, varscan2
- SGSM2 | c.1486G>A p.V496M (on ENST00000426855 / NM_001098509.2; = p.V541M on NM_014853.3) | Missense Mutation (SNP) | VAF 41/161 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.095); catalogued as rs202161088; called by muse, mutect2, varscan2
- SIDT1 | c.1912C>G p.L638V | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.034); catalogued as COSV53502922; called by muse, mutect2, varscan2
- SKIV2L | c.2306G>A p.S769N | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100514799, COSV61714504; called by muse, mutect2, varscan2
- SLC25A25 | c.367C>G p.L123V | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.21); catalogued as COSV100895359, COSV66087390; called by muse, mutect2
- SLC4A4 | c.2128C>G p.L710V (on ENST00000264485 / NM_001098484.3; = p.L666V on NM_003759.4) | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99141096; called by muse, mutect2, varscan2
- SLC5A2 | c.1894G>T p.E632* | Nonsense Mutation (SNP) | VAF 12/34 reads (35%) | catalogued as COSV100393337; called by muse, mutect2, varscan2
- SLC6A5 | c.1352G>A p.W451* | Nonsense Mutation (SNP) | VAF 40/175 reads (23%) | catalogued as COSV100117062; called by muse, mutect2, varscan2
- SLC7A4 | c.542C>G p.S181C | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV100298811, COSV60384085; called by muse, mutect2, varscan2
- SLIT1 | c.271C>A p.Q91K | Missense Mutation (SNP) | VAF 135/494 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.138); catalogued as COSV99822100; called by muse, mutect2, varscan2
- SPIN4 | c.330C>G p.I110M | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV100633394; called by muse, mutect2
- SPINK5 | c.2348A>C p.N783T | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.971); catalogued as COSV99807122; called by muse, mutect2, varscan2
- SPTA1 | c.4387G>A p.D1463N | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0.013); catalogued as COSV100935312; called by muse, mutect2, varscan2
- SRPRB | c.37G>A p.G13S | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs139369374, COSV101524169; called by muse, mutect2
- ST20 | c.196C>G p.L66V | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV99358300; called by muse, mutect2
- STK38 | c.227T>G p.F76C | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV100007448; called by muse, mutect2, varscan2
- SUPT6H | c.1838G>C p.R613T | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV100112629; called by muse, mutect2, varscan2
- TAF5L | c.913G>C p.E305Q | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0.058); catalogued as COSV99273509; called by muse, mutect2, varscan2
- TASOR2 | c.5195C>T p.T1732M | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs200385091, COSV60168038; called by muse, mutect2, varscan2
- TCAF2 | c.2433C>G p.I811M | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV100633673; called by muse, mutect2, varscan2
- TEAD4 | c.16G>A p.G6S | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.347); catalogued as rs764221350, COSV100622128; called by muse, mutect2, varscan2
- TMEM132A | c.526C>G p.R176G | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); catalogued as COSV99136533; called by muse, mutect2, varscan2
- TMEM161B | c.402G>C p.M134I | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.932); catalogued as COSV99494594; called by muse, mutect2, varscan2
- TMEM37 | c.175G>A p.G59R | Missense Mutation (SNP) | VAF 36/167 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as rs771796297, COSV99191681; called by muse, mutect2, varscan2
- TMUB2 | c.71C>G p.S24C (on ENST00000538716 / NM_001353177.2; = p.S4C on NM_024107.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV100116262; called by muse, mutect2, varscan2
- TMUB2 | c.470C>T p.A157V (on ENST00000538716 / NM_001353177.2; = p.A137V on NM_024107.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0.022); catalogued as rs766442596, COSV100116273; called by muse, varscan2
- TMUB2 | c.748C>T p.P250S (on ENST00000538716 / NM_001353177.2; = p.P230S on NM_024107.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV100116278, COSV99069339; called by muse, varscan2
- TNS3 | c.485T>A p.F162Y | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.92); PolyPhen possibly damaging (0.824); catalogued as COSV100236117; called by muse, mutect2, varscan2
- TP53BP2 | c.1436G>A p.G479D (on ENST00000343537 / NM_001031685.3; = p.G350D on NM_005426.2) | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as COSV100636742; called by muse, mutect2, varscan2
- TRIM63 | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as rs775364417, COSV65328674; called by muse, mutect2, varscan2
- TRIP12 | c.5975C>A p.S1992Y | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99390744; called by muse, mutect2
- TRPV1 | c.1298G>A p.R433H | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0.023); catalogued as rs1029040864, COSV99440297; called by muse, mutect2, varscan2
- TTYH1 | c.527G>A p.R176Q | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.089); catalogued as rs201121658; called by muse, mutect2, varscan2
- TUBD1 | c.593C>G p.S198* | Nonsense Mutation (SNP) | VAF 30/130 reads (23%) | catalogued as COSV100360206; called by muse, varscan2
- TUBD1 | c.410dup p.I138Hfs*42 | Frame Shift Ins (INS) | VAF 36/210 reads (17%) | catalogued as rs779487850; called by pindel, varscan2
- TUT4 | c.3181G>C p.E1061Q | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.999); catalogued as COSV99932642; called by muse, mutect2, varscan2
- UBE4A | c.62C>G p.S21C | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.921); catalogued as COSV99348430, COSV99348441; called by muse, mutect2, varscan2
- USP22 | c.604G>T p.D202Y | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99820413; called by muse, mutect2, varscan2
- USP37 | c.1775C>T p.S592F | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.42); catalogued as COSV99294714; called by muse, mutect2, varscan2
- VWA7 | c.1277C>A p.T426N | Missense Mutation (SNP) | VAF 7/154 reads (5%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.738); catalogued as COSV100991931; called by muse, mutect2
- WDR70 | c.918G>T p.A306= | Splice Region (SNP) | VAF 9/30 reads (30%) | catalogued as COSV99459686; called by muse, mutect2, varscan2
- YLPM1 | c.2827C>G p.Q943E | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.006); catalogued as COSV99458545, COSV99460814; called by muse, mutect2, varscan2
- ZFC3H1 | c.2146G>A p.D716N | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV101110649; called by muse, mutect2
- ZFHX4 | c.1002C>G p.S334R | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99265905; called by muse, mutect2, varscan2
- ZNF205 | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 55/208 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs763302642, COSV54620939, COSV99530545; called by muse, mutect2, varscan2
- ZNF208 | c.2572G>A p.E858K | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.957); catalogued as COSV101237164, COSV101237208, COSV101237273; called by muse, mutect2
- ZNF468 | c.133G>A p.V45I | Missense Mutation (SNP) | VAF 49/330 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.102); catalogued as rs759202350, COSV54693294; called by muse, mutect2, varscan2
- ZNF606 | c.2095C>T p.R699W | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs200784321; called by muse, mutect2, varscan2
- ZNF689 | c.1318C>T p.Q440* | Nonsense Mutation (SNP) | VAF 5/23 reads (22%) | catalogued as COSV99788095; called by muse, mutect2, varscan2
- ZNF766 | c.8A>C p.Q3P | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.015); catalogued as COSV101467005; called by muse, mutect2, varscan2
- FAT1 | c.12015_12016insAGTA p.P4007Ifs*45 | Frame Shift Ins (INS) | VAF 44/138 reads (32%) | called by mutect2, pindel, varscan2
- FAT1 | c.8780dup p.S2928Efs*2 | Frame Shift Ins (INS) | VAF 36/145 reads (25%) | called by mutect2, pindel, varscan2
- KCNAB2 | c.810_812dup p.Y270_Q271insH | In Frame Ins (INS) | VAF 4/24 reads (17%) | called by mutect2, pindel
- KMT2C | c.585_588del p.R196Kfs*9 | Frame Shift Del (DEL) | VAF 77/133 reads (58%) | called by mutect2, pindel, varscan2
- NAGLU | c.942_943del p.F314Lfs*2 | Frame Shift Del (DEL) | VAF 43/145 reads (30%) | called by mutect2, pindel, varscan2
- OR3A2 | c.671_673del p.I224del | In Frame Del (DEL) | VAF 18/100 reads (18%) | called by pindel, varscan2
- PCSK9 | c.275_276del p.E92Afs*78 | Frame Shift Del (DEL) | VAF 13/75 reads (17%) | called by pindel, varscan2
- PPM1D | c.1549del p.T517Lfs*5 | Frame Shift Del (DEL) | VAF 28/110 reads (25%) | called by mutect2, pindel, varscan2
- UPF1 | c.3053-10_3063del p.X1018_splice (on ENST00000599848 / NM_001297549.2; = p.X1007_splice on NM_002911.4) | Splice Site (DEL) | VAF 31/133 reads (23%) | called by mutect2, pindel
- ADCY5 | c.2889C>T p.T963= | Silent (SNP) | VAF 18/79 reads (23%) | catalogued as rs1018913781, COSV100568086; called by muse, mutect2, varscan2
- AGTRAP | c.153C>T p.I51= | Silent (SNP) | VAF 51/182 reads (28%) | catalogued as rs1379153111, COSV58669063; called by muse, mutect2, varscan2
- AKAP6 | c.6204G>A p.S2068= | Silent (SNP) | VAF 22/70 reads (31%) | catalogued as rs776043939, COSV99803058; called by muse, mutect2, varscan2
- ALOXE3 | c.222C>T p.Y74= | Silent (SNP) | VAF 28/78 reads (36%) | catalogued as rs572527913, COSV100503005; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AMBRA1 | c.453C>G p.L151= | Silent (SNP) | VAF 19/86 reads (22%) | catalogued as COSV100094878; called by muse, mutect2, varscan2
- ANKRD12 | c.639G>A p.V213= | Silent (SNP) | VAF 17/68 reads (25%) | catalogued as COSV100041819; called by muse, mutect2, varscan2
- ATOH7 | c.288G>A p.L96= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV101028525; called by muse, mutect2, varscan2
- ATP1A4 | c.888C>T p.I296= | Silent (SNP) | VAF 10/206 reads (5%) | catalogued as rs955817467, COSV100927614; called by muse, mutect2
- BDKRB1 | c.765C>T p.L255= | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as rs150459277; called by muse, mutect2, varscan2
- C1QC | c.297C>A p.P99= | Silent (SNP) | VAF 21/88 reads (24%) | catalogued as COSV101009513; called by muse, mutect2, varscan2
- C1R | c.222C>T p.F74= (on ENST00000536053 / NM_001354346.2; = p.F60= on NM_001733.7) | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as COSV99864847; called by muse, mutect2, varscan2
- CAND1 | c.3582G>A p.L1194= | Silent (SNP) | VAF 22/90 reads (24%) | catalogued as rs1188336242, COSV101607343; called by muse, mutect2, varscan2
- CATSPERD | c.1950G>A p.V650= | Silent (SNP) | VAF 34/102 reads (33%) | catalogued as COSV100486926; called by muse, varscan2
- CBARP | c.129G>A p.V43= (on ENST00000382477; = p.V49= on NM_152769.3) | Silent (SNP) | VAF 43/209 reads (21%) | catalogued as COSV99289814; called by muse, mutect2, varscan2
- CCDC141 | c.2520C>A p.L840= | Silent (SNP) | VAF 19/92 reads (21%) | catalogued as rs1229495014, COSV55384064, COSV99837218; called by muse, mutect2, varscan2
- CCL19 | c.36C>G p.L12= | Silent (SNP) | VAF 17/33 reads (52%) | catalogued as rs1271466737, COSV100323180; called by muse, mutect2, varscan2
- CLPB | c.1800C>G p.L600= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV99578478; called by muse, mutect2, varscan2
- CMIP | c.2205G>A p.K735= (on ENST00000537098 / NM_198390.2; = p.K641= on NM_030629.3) | Silent (SNP) | VAF 69/423 reads (16%) | catalogued as COSV101220948; called by muse, mutect2, varscan2
- COL6A5 | c.5914C>A p.R1972= (on ENST00000312481; = p.R1968= on NM_153264.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV55194741, COSV99594055; called by muse, mutect2, varscan2
- CPN1 | c.453G>A p.R151= | Silent (SNP) | VAF 28/103 reads (27%) | catalogued as COSV100962690; called by muse, mutect2, varscan2
- CRHR2 | c.690C>T p.I230= | Silent (SNP) | VAF 27/103 reads (26%) | catalogued as rs1410222378, COSV59264358; called by muse, mutect2, varscan2
- DIO3 | c.462C>T p.Y154= | Silent (SNP) | VAF 28/105 reads (27%) | catalogued as rs1359143742, COSV63774044; called by muse, mutect2, varscan2
- EP400 | c.6868C>T p.L2290= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as rs1406086537, COSV100201881; called by muse, mutect2, varscan2
- EPHA3 | c.2538C>T p.P846= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV100347337, COSV60713992; called by muse, mutect2, varscan2
- EPHB4 | c.396G>A p.E132= | Silent (SNP) | VAF 33/91 reads (36%) | catalogued as rs753084326, COSV100639593; called by muse, mutect2, varscan2
- FBXO27 | c.630C>T p.D210= | Silent (SNP) | VAF 77/241 reads (32%) | catalogued as rs552069426, COSV53072729; called by muse, mutect2, varscan2
- FMN2 | c.2814C>T p.P938= | Silent (SNP) | VAF 37/103 reads (36%) | catalogued as rs1183411950, COSV100148212; called by muse, varscan2
- GLUD2 | c.867C>T p.Y289= | Silent (SNP) | VAF 45/73 reads (62%) | catalogued as COSV100046999; called by muse, mutect2, varscan2
- GPC5 | c.1137G>A p.T379= | Silent (SNP) | VAF 39/141 reads (28%) | catalogued as rs371912542; called by muse, mutect2, varscan2
- HAPLN1 | c.39C>T p.C13= | Silent (SNP) | VAF 37/104 reads (36%) | catalogued as COSV99165111; called by muse, mutect2, varscan2
- HIPK3 | c.3021C>T p.A1007= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as rs758145137, COSV57564212; called by muse, mutect2, varscan2
- IGHM | c.825G>A p.E275= | Silent (SNP) | VAF 29/88 reads (33%) | catalogued as rs781916515; called by muse, mutect2, varscan2
- IGKV4-1 | c.273C>T p.S91= | Silent (SNP) | VAF 30/94 reads (32%) | catalogued as rs529546131; called by muse, mutect2, varscan2
- ISG20L2 | c.1020C>G p.V340= | Silent (SNP) | VAF 68/272 reads (25%) | catalogued as COSV100494069; called by muse, mutect2, varscan2
- ITGB6 | c.1701C>T p.S567= | Silent (SNP) | VAF 39/145 reads (27%) | catalogued as COSV99324823; called by muse, mutect2, varscan2
- JAG1 | c.2118C>T p.D706= | Silent (SNP) | VAF 17/82 reads (21%) | catalogued as COSV99653282; called by muse, mutect2, varscan2
- KRT79 | c.168C>G p.G56= | Silent (SNP) | VAF 33/139 reads (24%) | catalogued as COSV100398513; called by muse, mutect2, varscan2
- KRT83 | c.522G>A p.V174= | Silent (SNP) | VAF 43/183 reads (23%) | catalogued as rs763480224, COSV99531806; called by muse, mutect2, varscan2
- LINGO2 | c.825G>C p.L275= | Silent (SNP) | VAF 30/218 reads (14%) | catalogued as COSV100431007; called by muse, mutect2, varscan2
- LIPE | c.1887G>A p.R629= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as COSV99734316; called by muse, mutect2, varscan2
- LOXL2 | c.921C>T p.F307= | Silent (SNP) | VAF 34/147 reads (23%) | catalogued as COSV66692411; called by muse, mutect2, varscan2
- MBD3 | c.240C>T p.R80= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as rs897402816, COSV99337049; called by muse, mutect2, varscan2
- MC3R | c.414C>T p.I138= | Silent (SNP) | VAF 33/102 reads (32%) | catalogued as rs1421808595, COSV54764322; called by muse, mutect2, varscan2
- MFSD2A | c.1317C>T p.I439= (on ENST00000372809 / NM_001136493.3; = p.I426= on NM_032793.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as COSV100861725; called by muse, mutect2, varscan2
- MMP27 | c.1137C>T p.A379= | Silent (SNP) | VAF 48/156 reads (31%) | catalogued as rs768167008, COSV99498131, COSV99498595; called by muse, mutect2, varscan2
- MYO18B | c.7431G>A p.T2477= | Silent (SNP) | VAF 26/98 reads (27%) | catalogued as rs777532590, COSV59134202; called by muse, mutect2, varscan2
- NUBP2 | c.522G>A p.L174= | Silent (SNP) | VAF 34/155 reads (22%) | catalogued as COSV99236632; called by muse, mutect2, varscan2
- OLFML2A | c.339G>A p.A113= | Silent (SNP) | VAF 21/79 reads (27%) | catalogued as rs370096635, COSV100053768, COSV59160584; called by muse, mutect2, varscan2
- OR13C9 | c.885C>T p.I295= | Silent (SNP) | VAF 47/234 reads (20%) | catalogued as rs369126446, COSV52241126, COSV99403524; called by muse, mutect2, varscan2
- OR2A7 | c.732C>T p.L244= | Silent (SNP) | VAF 40/471 reads (8%) | catalogued as rs769065362, COSV101512232; called by muse, mutect2
- OR2Z1 | c.234C>T p.I78= | Silent (SNP) | VAF 34/137 reads (25%) | catalogued as rs201431397; called by muse, mutect2, varscan2
- PARD3 | c.1041C>T p.A347= | Silent (SNP) | VAF 39/158 reads (25%) | catalogued as COSV100401658; called by muse, mutect2, varscan2
- PLOD1 | c.678G>A p.V226= | Silent (SNP) | VAF 43/137 reads (31%) | catalogued as rs371007185; ClinVar: likely benign; called by muse, mutect2, varscan2
- RAD23B | c.1149G>C p.V383= | Silent (SNP) | VAF 44/116 reads (38%) | catalogued as COSV63658714, COSV63658928; called by muse, varscan2
- SCAMP3 | c.714C>T p.F238= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as rs772555464, COSV100226856; called by muse, mutect2, varscan2
- SCEL | c.756A>G p.E252= (on ENST00000349847 / NM_144777.3; = p.E232= on NM_003843.4) | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as rs1269827633, COSV100583097; called by muse, mutect2, varscan2
- SLC12A3 | c.663C>T p.L221= | Silent (SNP) | VAF 34/135 reads (25%) | catalogued as COSV99344564; called by muse, mutect2, varscan2
- SMOC1 | c.165C>A p.I55= | Silent (SNP) | VAF 48/156 reads (31%) | catalogued as COSV100734731; called by muse, mutect2, varscan2
- SNX29 | c.771G>C p.R257= | Silent (SNP) | VAF 23/85 reads (27%) | catalogued as COSV100029672; called by muse, mutect2, varscan2
- STK10 | c.2613G>A p.A871= | Silent (SNP) | VAF 72/218 reads (33%) | catalogued as rs763279035, COSV51573769; called by muse, mutect2, varscan2
- SYMPK | c.2172G>A p.E724= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as COSV99841946; called by muse, mutect2, varscan2
- SZRD1 | c.237C>T p.S79= | Silent (SNP) | VAF 47/157 reads (30%) | catalogued as COSV100981539; called by muse, mutect2, varscan2
- TCP11L1 | c.219C>T p.V73= | Silent (SNP) | VAF 36/141 reads (26%) | catalogued as COSV100178293; called by muse, mutect2, varscan2
- THBS3 | c.2247C>A p.L749= | Silent (SNP) | VAF 19/65 reads (29%) | catalogued as COSV100857675; called by muse, mutect2, varscan2
- TMEM72 | c.78C>T p.I26= | Silent (SNP) | VAF 43/154 reads (28%) | catalogued as rs532437325, COSV67460513; called by muse, mutect2, varscan2
- TMPRSS11D | c.648G>C p.L216= | Silent (SNP) | VAF 32/120 reads (27%) | catalogued as COSV99384903; called by muse, mutect2, varscan2
- TMUB2 | c.819C>T p.L273= (on ENST00000538716 / NM_001353177.2; = p.L253= on NM_024107.3 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 46/192 reads (24%) | catalogued as rs772489403, COSV100116279; called by muse, varscan2
- TRPV6 | c.1743C>T p.I581= | Silent (SNP) | VAF 119/235 reads (51%) | catalogued as rs147746494; called by muse, mutect2, varscan2
- UNC5B | c.273C>T p.H91= | Silent (SNP) | VAF 40/166 reads (24%) | catalogued as rs770451311, COSV100101102; called by muse, mutect2, varscan2
- VCAM1 | c.1065G>A p.L355= | Silent (SNP) | VAF 29/139 reads (21%) | catalogued as rs908431256, COSV99658122; called by muse, mutect2, varscan2
- VWF | c.402T>C p.Y134= | Silent (SNP) | VAF 35/164 reads (21%) | catalogued as rs1257738113, COSV99779736; called by muse, mutect2, varscan2
- WDR59 | c.582C>T p.I194= | Silent (SNP) | VAF 28/162 reads (17%) | catalogued as COSV50934429; called by muse, mutect2, varscan2
- XCR1 | c.390G>A p.S130= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs761886960, COSV100499432; called by muse, mutect2, varscan2
- XPC | c.2805C>T p.F935= | Silent (SNP) | VAF 27/108 reads (25%) | catalogued as COSV99542495; called by muse, mutect2, varscan2
- ZNF347 | c.2190C>T p.I730= | Silent (SNP) | VAF 48/200 reads (24%) | catalogued as COSV100498370; called by muse, mutect2, varscan2
- ZSCAN18 | c.51G>A p.P17= | Silent (SNP) | VAF 44/152 reads (29%) | catalogued as rs531440981, COSV53735635; called by muse, mutect2, varscan2
- ZYG11B | c.2202C>T p.P734= | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as COSV99597695; called by muse, mutect2, varscan2
- AP3D1 | c.2602-1043G>A | Intron (SNP) | VAF 13/65 reads (20%) | catalogued as rs772098647, COSV100642660, COSV100642889; called by muse, mutect2, varscan2
- CLDN16 | c.-18G>A | 5'UTR (SNP) | VAF 37/132 reads (28%) | catalogued as COSV99290302; called by muse, mutect2, varscan2
- DCHS2 | n.1458A>C | RNA (SNP) | VAF 24/113 reads (21%) | catalogued as COSV100252669; called by muse, mutect2, varscan2
- OR5AU1 | c.-113G>C | 5'UTR (SNP) | VAF 53/230 reads (23%) | catalogued as COSV100436181; called by muse, mutect2, varscan2
- SNORD115-26 | n.34G>C | RNA (SNP) | VAF 146/602 reads (24%) | called by muse, mutect2, varscan2
- TBC1D12 | c.-1G>A | 5'UTR (SNP) | VAF 14/45 reads (31%) | catalogued as rs762145762, COSV56552290, COSV56558736; called by muse, mutect2, varscan2
- UCHL5 | chr1:193059879 G>C | 5'Flank (SNP) | VAF 10/24 reads (42%) | catalogued as COSV100814669; called by muse, mutect2, varscan2
